Somatic mutation profile of tumor specimen TCGA-P3-A6T7-01A (aliquot TCGA-P3-A6T7-01A-11D-A34J-08) from TCGA case TCGA-P3-A6T7, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 55.6 years (20,301 days).
Specimen TCGA-P3-A6T7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7fe252c-3e56-4c7f-8fc0-283527798ccd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P3-A6T7-10A (Blood Derived Normal), aliquot TCGA-P3-A6T7-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c3d85e4-7dad-4bcb-ab55-d4416e6552c2

The open-access MAF lists 144 somatic variants for this specimen: 107 protein-altering or splice-affecting, 33 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 33, Frame Shift Del 6, Nonsense Mutation 4, Frame Shift Ins 4, Splice Region 2, Splice Site 2, In Frame Del 1, 5'Flank 1, Intron 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABI3BP | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 90/220 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs372669157, COSV52540615; called by muse, mutect2, varscan2
- APLF | c.986C>G p.S329W | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100377003, COSV58143504; called by muse, mutect2, varscan2
- ATXN3 | c.189+2T>C p.X63_splice | Splice Site (SNP) | VAF 22/135 reads (16%) | catalogued as COSV100515579; called by mutect2, varscan2
- BACE1 | c.259A>G p.T87A | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV100475290; called by muse, mutect2, varscan2
- BARHL2 | c.659G>A p.S220N | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100966099; called by muse, mutect2, varscan2
- BFSP1 | c.779A>G p.Y260C | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100925445; called by muse, mutect2
- C4orf45 | c.182C>G p.S61* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as COSV101465168; called by muse, mutect2, varscan2
- C9orf64 | c.27A>T p.E9D | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as COSV100123637; called by muse, mutect2, varscan2
- CACNA1I | c.4340G>A p.R1447Q | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs1305306479, COSV60810697; called by muse, mutect2, varscan2
- CASD1 | c.2176A>G p.I726V | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV99802994; called by muse, mutect2, varscan2
- CCDC191 | c.2017C>T p.R673W | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs780918643, COSV99878551; called by muse, mutect2, varscan2
- CELSR1 | c.4015C>T p.R1339W | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99419784; called by muse, mutect2, varscan2
- CELSR2 | c.2877G>T p.Q959H | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99604628; called by muse, mutect2
- CFAP94 | c.1716C>G p.I572M (on ENST00000320267 / NM_001352064.2; = p.I578M on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100209680, COSV57231620; called by muse, mutect2, varscan2
- CHD6 | c.796C>G p.L266V | Missense Mutation (SNP) | VAF 89/356 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV100498252, COSV100498613; called by muse, mutect2, varscan2
- CIITA | c.3010G>T p.V1004F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100162526; called by mutect2, varscan2
- CLCNKA | c.1988G>C p.R663T | Missense Mutation (SNP) | VAF 57/239 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100510314; called by muse, mutect2, varscan2
- CNNM1 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV100763972; called by muse, mutect2, varscan2
- CUL9 | c.476C>G p.T159S | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV99335930; called by muse, mutect2, varscan2
- DCLK1 | c.155C>G p.S52C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV55210078, COSV99712785; called by muse, mutect2, varscan2
- DDX41 | c.594G>C p.K198N | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100286796; called by muse, mutect2, varscan2
- EHBP1L1 | c.3239A>G p.Y1080C | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV100499987; called by muse, mutect2, varscan2
- EPHA3 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs764139832, COSV60693541, COSV60725620; called by muse, mutect2, varscan2
- EPHA3 | c.1750G>T p.G584C | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.417); catalogued as COSV60721550, COSV60731904; called by muse, mutect2, varscan2
- EPHA7 | c.1909C>T p.R637C | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as rs1270476760, COSV65180782, COSV65184618, COSV65190054; called by muse, mutect2, varscan2
- EPS15 | c.1010C>T p.T337I | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); catalogued as rs762919510, COSV100869598; called by muse, mutect2, varscan2
- FANCM | c.2831C>G p.S944C | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99951547; called by muse, mutect2, varscan2
- FBXW7 | c.502-1G>C p.X168_splice (on ENST00000281708 / NM_001349798.2; = p.X88_splice on NM_018315.5) | Splice Site (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99656634, COSV99662518; called by muse, mutect2
- FHDC1 | c.3185G>A p.R1062Q | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs774934667, COSV99471239, COSV99471650; called by muse, mutect2, varscan2
- FLVCR1 | c.1538C>A p.S513Y | Missense Mutation (SNP) | VAF 64/331 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100875113; called by muse, mutect2, varscan2
- FOLH1 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV99923826; called by muse, mutect2, varscan2
- FOXRED2 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99340997, COSV99341102; called by muse, mutect2, varscan2
- GABRG2 | c.421A>G p.M141V | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.841); catalogued as rs926095904, COSV100729821; called by muse, mutect2, varscan2
- GIMAP1 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.069); catalogued as rs142041443; called by muse, mutect2, varscan2
- GPER1 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs1172100515, COSV52468666; called by muse, mutect2, varscan2
- GPRIN3 | c.1054C>G p.H352D | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV100310959; called by muse, mutect2, varscan2
- GRK1 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as rs368488746; called by muse, mutect2
- GRM3 | c.1676T>G p.L559R | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.994); catalogued as COSV100862808; called by muse, mutect2, varscan2
- HCFC1R1 | c.282G>T p.R94S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.225); catalogued as COSV99560794; called by muse, mutect2, varscan2
- HECTD1 | c.6611C>G p.S2204C | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV101237488; called by muse, mutect2, varscan2
- HSPBP1 | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 33/170 reads (19%) | catalogued as COSV99729246; called by muse, mutect2, varscan2
- HYDIN | c.9991G>A p.E3331K | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs201494207; called by muse, mutect2, varscan2
- IDS | c.454A>T p.S152C | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM118967, COSV100558171; called by muse, mutect2, varscan2
- IDUA | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs141461803; ClinVar: uncertain significance; called by muse, varscan2
- KCNK5 | c.608C>A p.T203N | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100851923; called by muse, mutect2, varscan2
- KIF15 | c.1652T>G p.F551C | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100393187; called by muse, mutect2, varscan2
- KIF21B | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV100145035; called by muse, mutect2, varscan2
- MAMSTR | c.802C>G p.P268A (on ENST00000318083 / NM_001130915.2; = p.P165A on NM_182574.2) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100540653, COSV100540744; called by muse, mutect2, varscan2
- MANEAL | c.1155G>C p.E385D (on ENST00000373045 / NM_001113482.1; = p.E163D on NM_152496.2) | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV100203975; called by muse, mutect2, varscan2
- MDFI | c.580T>A p.S194T | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100025763; called by muse, mutect2, varscan2
- MUC5B | c.11063G>A p.G3688E | Missense Mutation (SNP) | VAF 88/345 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV101500571; called by muse, mutect2, varscan2
- MYBPC2 | c.3278A>G p.K1093R | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.601); catalogued as COSV100731998; called by muse, varscan2
- MYOZ1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 62/231 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63771859; called by muse, mutect2, varscan2
- NFE2L3 | c.1054C>A p.P352T | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99283975; called by muse, mutect2, varscan2
- NFKBIL1 | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV101092958; called by muse, mutect2, varscan2
- NLRP8 | c.1282G>A p.V428I | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.177); catalogued as rs759351908, COSV52585627; called by muse, mutect2, varscan2
- NR1H2 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs1404324508, COSV99516518; called by muse, mutect2, varscan2
- NYNRIN | c.2723A>T p.K908M | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV101230680; called by muse, mutect2, varscan2
- OGFOD1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100273154, COSV60200638; called by muse, mutect2, varscan2
- OR10A3 | c.143T>G p.I48S | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV100660325; called by muse, mutect2, varscan2
- OR56A3 | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 58/226 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100290353; called by muse, mutect2, varscan2
- OR5AS1 | c.302T>A p.M101K | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV100546359; called by muse, mutect2, varscan2
- OR5F1 | c.510C>A p.D170E | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV99558887; called by muse, mutect2, varscan2
- OR5M3 | c.513G>C p.E171D | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.927); catalogued as COSV100392669; called by muse, mutect2, varscan2
- OTOA | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs145435704; called by muse, mutect2, varscan2
- PCDHA8 | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as rs1554139301, COSV65335257; called by muse, mutect2, varscan2
- PCDHB3 | c.731A>G p.Q244R | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.743); catalogued as COSV99166414; called by muse, mutect2, varscan2
- PEX3 | c.625C>G p.L209V | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100852241; called by muse, mutect2, varscan2
- PHACTR2 | c.749C>G p.S250* | Nonsense Mutation (SNP) | VAF 37/159 reads (23%) | catalogued as COSV99992250; called by muse, mutect2, varscan2
- PHF3 | c.3964A>G p.I1322V | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.519); catalogued as COSV100013843; called by muse, mutect2, varscan2
- PIGZ | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99433945; called by muse, mutect2, varscan2
- PIK3C2G | c.3578G>A p.S1193N (on ENST00000676171; = p.S1152N on NM_004570.5) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99853666; called by muse, mutect2, varscan2
- PINK1 | c.958_959+1del | In Frame Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs761346571; called by pindel, varscan2
- PLG | c.135T>A p.S45R | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV99805057; called by muse, mutect2, varscan2
- PPP6C | c.502C>G p.P168A | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101001244, COSV65208324; called by muse, varscan2
- RNF20 | c.1817C>G p.S606C | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV101206575; called by muse, mutect2, varscan2
- SLAMF7 | c.651T>C p.G217= | Splice Region (SNP) | VAF 55/231 reads (24%) | catalogued as COSV100833358; called by muse, mutect2, varscan2
- SLC9A6 | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as COSV100857905, COSV100857943; called by muse, mutect2, varscan2
- SMAD4 | c.1096C>A p.Q366K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as CM147871, COSV61690182, COSV61693326, COSV61696902; called by muse, mutect2, varscan2
- SPATA19 | c.138A>T p.T46= | Splice Region (SNP) | VAF 23/74 reads (31%) | catalogued as COSV100141245; called by muse, mutect2, varscan2
- STXBP5L | c.1771T>A p.S591T | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.197); catalogued as COSV99876113; called by muse, mutect2, varscan2
- SYNE1 | c.4263G>C p.K1421N (on ENST00000367255 / NM_182961.4; = p.K1428N on NM_033071.3) | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99576254; called by muse, mutect2, varscan2
- SYNM | c.1649G>C p.R550T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100153020; called by muse, mutect2, varscan2
- TARDBP | c.593G>A p.C198Y | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV99534434; called by muse, mutect2, varscan2
- TBX2 | c.1810G>A p.G604S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs147014278, COSV53600499; called by muse, mutect2, varscan2
- TMC6 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.636); catalogued as rs201290210, COSV59808457; called by muse, mutect2, varscan2
- TP53 | c.713del p.C238Lfs*9 | Frame Shift Del (DEL) | VAF 19/70 reads (27%) | catalogued as CM034930, COSV52661646, COSV52706816, COSV52804264; called by mutect2, pindel, varscan2
- TTBK1 | c.1504G>A p.G502S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV52490850; called by muse, mutect2, varscan2
- TTN | c.44093G>A p.R14698Q (on ENST00000591111; = p.R7274Q on NM_003319.4) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | PolyPhen probably damaging (0.996); catalogued as rs558487304, COSV100626900; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13B | c.2285C>G p.S762C | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as COSV100663326; called by muse, mutect2, varscan2
- WTAP | c.731C>G p.S244C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.303); catalogued as rs973976887, COSV64330590; called by muse, mutect2, varscan2
- ZNF337 | c.181A>T p.I61F | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.267); catalogued as COSV99430406; called by muse, mutect2, varscan2
- ZNF432 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 46/276 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99659356; called by muse, mutect2, varscan2
- ZNF516 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.188); catalogued as rs374622201; called by muse, mutect2
- ZNF568 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 43/165 reads (26%) | catalogued as COSV100451410; called by muse, mutect2, varscan2
- ZNF664 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as rs1254681742, COSV61878195; called by muse, mutect2, varscan2
- ABCA5 | c.539dup p.D181Rfs*21 | Frame Shift Ins (INS) | VAF 38/252 reads (15%) | called by mutect2, pindel, varscan2
- BPNT2 | c.519_538del p.D174Gfs*21 | Frame Shift Del (DEL) | VAF 20/117 reads (17%) | called by mutect2, pindel
- CHD8 | c.6155dup p.L2053Sfs*14 (on ENST00000646647 / NM_001170629.2; = p.L1774Sfs*14 on NM_020920.4) | Frame Shift Ins (INS) | VAF 11/62 reads (18%) | called by mutect2, pindel, varscan2
- GFM2 | c.1616dup p.H539Qfs*7 | Frame Shift Ins (INS) | VAF 16/90 reads (18%) | called by mutect2, pindel, varscan2
- MYO5B | c.1703del p.N568Tfs*13 | Frame Shift Del (DEL) | VAF 37/103 reads (36%) | called by mutect2, pindel, varscan2
- MYO5B | c.1702A>G p.N568D | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by mutect2, varscan2
- PPIAL4A | c.276del p.H92Qfs*41 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- RNF146 | c.356_359del p.E119Afs*20 (on ENST00000368314 / NM_001242850.2; = p.E118Afs*20 on NM_030963.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 19/118 reads (16%) | called by mutect2, pindel, varscan2
- SEC24D | c.2447_2459del p.M816Tfs*20 | Frame Shift Del (DEL) | VAF 22/119 reads (18%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.1801C>A p.Q601K | Missense Mutation (SNP) | VAF 106/212 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- VWA7 | c.1401dup p.Y468Ifs*107 | Frame Shift Ins (INS) | VAF 13/71 reads (18%) | called by mutect2, pindel, varscan2
- ANK3 | c.7044A>G p.R2348= | Silent (SNP) | VAF 40/162 reads (25%) | catalogued as COSV99781955; called by muse, mutect2, varscan2
- ARID4A | c.1950T>C p.D650= | Silent (SNP) | VAF 49/103 reads (48%) | catalogued as COSV100794598; called by muse, mutect2, varscan2
- B3GALT5 | c.657C>T p.Y219= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as rs529977380, COSV100563313; called by muse, mutect2
- BAHCC1 | c.1272C>T p.H424= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs367646703; called by muse, mutect2, varscan2
- BRD9 | c.996G>C p.G332= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100057532; called by muse, mutect2, varscan2
- C1QL3 | c.48C>T p.A16= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1396337324, COSV100127068; called by muse, mutect2, varscan2
- DGAT1 | c.426C>G p.V142= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1554847731, COSV100184185; called by muse, mutect2
- DST | c.12903A>G p.E4301= (on ENST00000361203 / NM_001374722.1; = p.E1889= on NM_015548.5) | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99759330; called by muse, mutect2, varscan2
- GABRA1 | c.606A>G p.P202= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV99196228; called by muse, mutect2, varscan2
- IGHV1-18 | c.156T>G p.G52= | Silent (SNP) | VAF 150/367 reads (41%) | catalogued as rs367669307; called by muse, mutect2, varscan2
- MLYCD | c.861C>T p.I287= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs957509653, COSV99299425; called by muse, mutect2, varscan2
- NFE2L1 | c.1893C>T p.I631= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV62582916; called by muse, mutect2, varscan2
- NFE2L1 | c.2250C>T p.L750= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as COSV62583701; called by muse, mutect2, varscan2
- OR2T2 | c.105C>A p.I35= | Silent (SNP) | VAF 26/231 reads (11%) | catalogued as rs528774471, COSV61618126, COSV61618913; called by muse, mutect2, varscan2
- OR51B5 | c.816C>T p.L272= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs866448073, COSV56176840; called by muse, mutect2, varscan2
- OR6S1 | c.765T>C p.Y255= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as rs760298015, COSV100289498; called by muse, mutect2, varscan2
- PCDHB12 | c.2211G>A p.V737= | Silent (SNP) | VAF 37/187 reads (20%) | catalogued as rs781856654, COSV99507737; called by muse, mutect2, varscan2
- PCNX3 | c.513C>T p.S171= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100482708; called by muse, mutect2
- PI4KA | c.4548A>G p.E1516= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99748299; called by muse, mutect2, varscan2
- PKHD1L1 | c.10986T>C p.P3662= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs1157045209, COSV101006737; called by muse, mutect2, varscan2
- RIC1 | c.2883T>A p.L961= | Silent (SNP) | VAF 42/305 reads (14%) | catalogued as COSV99317875; called by muse, mutect2, varscan2
- SLC24A5 | c.258C>G p.V86= | Silent (SNP) | VAF 45/186 reads (24%) | catalogued as COSV100415246; called by muse, mutect2, varscan2
- SLC51A | c.216C>T p.A72= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as rs762228183, COSV99580431; called by muse, mutect2, varscan2
- SPHKAP | c.537G>A p.L179= | Silent (SNP) | VAF 70/126 reads (56%) | catalogued as COSV100764505, COSV60880812; called by muse, mutect2, varscan2
- STXBP4 | c.1635T>C p.S545= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as COSV100894854; called by muse, mutect2, varscan2
- TDRD6 | c.3048A>G p.S1016= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as rs1242735889, COSV100288230; called by muse, mutect2, varscan2
- TPRA1 | c.1095C>T p.S365= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs372160309, COSV99952438; called by muse, mutect2, varscan2
- TRABD2A | c.471C>T p.A157= | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as rs552109610, COSV59106289; called by muse, mutect2, varscan2
- TTC9B | c.291G>A p.A97= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV99454798; called by muse, mutect2, varscan2
- TTN | c.17694C>T p.D5898= (on ENST00000591111; = p.D4971= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/124 reads (46%) | catalogued as rs372400829; ClinVar: likely benign; called by muse, mutect2, varscan2
- VPS4A | c.129C>T p.I43= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV99652116; called by muse, mutect2, varscan2
- ZNF629 | c.1137C>T p.C379= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV99354466; called by muse, mutect2, varscan2
- ZNF692 | c.1131G>A p.K377= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV60639162; called by muse, mutect2
- C11orf49 | chr11:47164245 G>A | 3'Flank (SNP) | VAF 6/31 reads (19%) | catalogued as rs951718436, COSV99562660; called by muse, mutect2, varscan2
- CDH23 | c.1449+45G>A | Intron (SNP) | VAF 41/145 reads (28%) | catalogued as rs752614410, COSV54932402; called by muse, mutect2, varscan2
- RING1 | chr6:33207842 G>A | 5'Flank (SNP) | VAF 4/15 reads (27%) | catalogued as rs1365862233; called by muse, mutect2, varscan2
- ZNF271P | n.2256G>A | RNA (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
